Surgical pathology report (de-identified scan), TCGA case TCGA-QH-A65R, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Fondazione-Besta, specimen TCGA-QH-A65R-01A (Primary Tumor).

OBJECT: PATHOLOGIST REPORT

Code:

Gender: F

Age:

Date of surgery:

Localisation: temporal lobe

Diagnosis: anaplastic oligodendroglioma (grade 3 WHO)

Name of Pathologist:

*Oligodendroglioma,
anaplastic 9451/3
Site path Brain, temporal lobe
C71.2
CSF Brain NOS C71.9
JW 4/19/13*

PIPA Discrepancy		☒

Source: NCI Genomic Data Commons file 9b174071-7094-48dd-8bcf-0a130d4d1ba4 (TCGA-QH-A65R.B1ADFF4F-266F-45E8-B2E7-48EBFEEEE8FF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).